Somatic mutation profile of tumor specimen TCGA-IB-A5ST-01A (aliquot TCGA-IB-A5ST-01A-11D-A32N-08) from TCGA case TCGA-IB-A5ST, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.8 years (23,672 days).
Specimen TCGA-IB-A5ST-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fb01b3c-0d8a-450d-94f4-ef6502661ef9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-A5ST-10A (Blood Derived Normal), aliquot TCGA-IB-A5ST-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7c66587-c3fe-4d4b-abf9-5f961bba8512

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD34B | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 25/906 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100103469; called by muse, mutect2
- CBLL2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60368461; called by muse, mutect2
- CSPG4 | c.5888A>T p.Q1963L | Missense Mutation (SNP) | VAF 24/605 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100413631; called by muse, mutect2
- ABCA4 | c.1491C>T p.F497= | Silent (SNP) | VAF 21/722 reads (3%) | catalogued as rs1384070343, COSV64673623; called by muse, mutect2
- ARID1B | c.6183G>A p.S2061= | Silent (SNP) | VAF 46/1198 reads (4%) | catalogued as rs373301793, COSV51649890; called by muse, mutect2
- ITIH5 | c.612G>A p.P204= | Silent (SNP) | VAF 29/814 reads (4%) | catalogued as rs1425543668, COSV99904196; called by muse, mutect2
- LAYN | c.780A>G p.R260= (on ENST00000375615 / NM_001258390.1; = p.R252= on NM_178834.5) | Silent (SNP) | VAF 61/2085 reads (3%) | catalogued as COSV100986185; called by muse, mutect2
